Somatic mutation profile of tumor specimen TCGA-CM-4752-01A (aliquot TCGA-CM-4752-01A-01D-1408-10) from TCGA case TCGA-CM-4752, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 58.9 years (21,519 days).
Specimen TCGA-CM-4752-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8a93d8c-0e31-4014-98a9-1da0f1053049.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-4752-10A (Blood Derived Normal), aliquot TCGA-CM-4752-10A-01D-1408-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19f871ec-6d73-4193-90e8-1b1d504bffaa

The open-access MAF lists 136 somatic variants for this specimen: 101 protein-altering or splice-affecting, 35 silent.
By variant classification: Missense Mutation 88, Silent 35, Nonsense Mutation 6, Frame Shift Ins 2, Splice Region 2, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 20/181 reads (11%) | catalogued as rs80358438, CM110364, COSV66448948, COSV66461911; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CLCN1 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 54/217 reads (25%) | catalogued as rs759761559, CM124358, COSV58368536; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 30/67 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACTL7B | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs1447439158, COSV65927054; called by muse, mutect2, varscan2
- ADCY4 | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as rs76097666, COSV60252995; called by muse, mutect2, varscan2
- ADGRG7 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV56294932; called by muse, mutect2, varscan2
- AGAP6 | c.1954G>A p.V652M (on ENST00000374056 / NM_001365867.1; = p.V675M on NM_001077665.2) | Missense Mutation (SNP) | VAF 40/323 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.962); catalogued as rs1477733320, COSV100929071; called by muse, mutect2, varscan2
- AOC3 | c.456G>T p.M152I | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as COSV53825296; called by muse, mutect2, varscan2
- APC | c.1567A>T p.K523* | Nonsense Mutation (SNP) | VAF 24/100 reads (24%) | catalogued as COSV99967016; called by muse, mutect2, varscan2
- APC | c.4391_4394del p.E1464Vfs*8 | Frame Shift Del (DEL) | VAF 20/104 reads (19%) | catalogued as rs387906234; called by mutect2, pindel, varscan2
- ARAP1 | c.2952C>T p.C984= (on ENST00000393609 / NM_001040118.2; = p.C739= on NM_015242.4) | Splice Region (SNP) | VAF 28/85 reads (33%) | catalogued as rs1177086237, COSV61990231; called by muse, mutect2, varscan2
- ARID3B | c.1562C>T p.T521M (on ENST00000622429 / NM_001307939.1; = p.T520M on NM_006465.4) | Missense Mutation (SNP) | VAF 48/216 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs772265663, COSV60556913; called by muse, mutect2, varscan2
- ART5 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as rs757415100, COSV63364286; called by muse, mutect2, varscan2
- ASCC3 | c.3788T>G p.L1263W | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61226825; called by muse, mutect2, varscan2
- ATP10A | c.536C>A p.A179E | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63515215; called by muse, mutect2, varscan2
- ATP6V1C1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1388747539, COSV67777615; called by muse, mutect2, varscan2
- ATP8B2 | c.1657G>A p.V553I (on ENST00000672630; = p.V520I on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.92); PolyPhen benign (0.063); catalogued as rs367849376; called by muse, mutect2, varscan2
- BABAM1 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV100845693, COSV63920164; called by muse, mutect2, varscan2
- BAIAP2 | c.1408G>A p.D470N | Missense Mutation (SNP) | VAF 35/279 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs768070859, COSV58334021; called by muse, mutect2, varscan2
- BCAN | c.2164C>T p.H722Y | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61256020; called by muse, mutect2, varscan2
- BDP1 | c.1073A>G p.E358G | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100702918; called by muse, mutect2
- C2orf16 | c.5324G>A p.R1775H | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs540398491, COSV62673627; called by muse, mutect2, varscan2
- CASKIN2 | c.2926G>A p.V976M | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs767227310, COSV58593955; called by muse, mutect2, varscan2
- CAV2 | c.348G>T p.M116I | Missense Mutation (SNP) | VAF 79/238 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV56063677; called by muse, mutect2, varscan2
- CFAP69 | c.1169G>A p.G390D | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as rs1162277201, COSV60184880; called by muse, mutect2, varscan2
- CKAP2L | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV56696017; called by muse, mutect2, varscan2
- CNOT1 | c.4837G>C p.D1613H | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV99799857; called by muse, mutect2
- COL4A4 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 18/209 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV61630625; called by muse, mutect2
- CSF2RB | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.474); catalogued as rs776366819, COSV53256508; called by muse, mutect2, varscan2
- CTNNB1 | c.1856G>A p.C619Y | Missense Mutation (SNP) | VAF 47/292 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.391); catalogued as COSV100845897; called by muse, mutect2, varscan2
- CYP2W1 | c.194C>T p.P65L | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs890133451, COSV58269269; called by muse, mutect2, varscan2
- DAGLA | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.988); catalogued as rs772726869, COSV57193833; called by muse, mutect2, varscan2
- DCAKD | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs139056062; called by muse, mutect2, varscan2
- DNAH2 | c.6508G>A p.V2170M | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779013637, COSV66717956; called by muse, mutect2, varscan2
- DNASE1L2 | c.458C>T p.T153M | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.24); catalogued as COSV57038297; called by muse, mutect2, varscan2
- ECE1 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs1305763532, COSV51662368; called by muse, mutect2, varscan2
- EEF1B2 | c.66G>T p.K22N | Missense Mutation (SNP) | VAF 64/354 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV51908723; called by muse, mutect2, varscan2
- EFEMP1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62615463; called by muse, mutect2, varscan2
- EPB41 | c.2486A>G p.D829G (on ENST00000343067 / NM_001166005.2; = p.D553G on NM_004437.4) | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58042986; called by muse, mutect2, varscan2
- EPN3 | c.1783T>G p.S595A | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as rs1311272086, COSV99276847; called by muse, varscan2
- ETV3L | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs776369446, COSV71901013; called by muse, mutect2, varscan2
- FAM13A | c.2713G>A p.D905N | Missense Mutation (SNP) | VAF 48/332 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); catalogued as rs563302433, COSV51996079; called by muse, mutect2, varscan2
- FAM47A | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.071); catalogued as rs768919658, COSV60495244; called by muse, mutect2
- FAM98A | c.1388G>A p.G463E | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.923); catalogued as rs755736838, COSV99479186; called by muse, mutect2, varscan2
- FBN1 | c.2887G>A p.E963K | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as COSV57312671; called by muse, mutect2
- FREM2 | c.5677G>A p.V1893I | Missense Mutation (SNP) | VAF 43/392 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs548177107, COSV54832643; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMPD2 | c.3509C>T p.A1170V | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1478579196, COSV59715574; called by muse, mutect2, varscan2
- FZD2 | c.1535C>T p.P512L | Missense Mutation (SNP) | VAF 19/138 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV100190341; called by muse, mutect2, varscan2
- GLI3 | c.2990C>T p.A997V | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV67886636; called by muse, mutect2, varscan2
- GPCPD1 | c.1958T>A p.L653* | Nonsense Mutation (SNP) | VAF 23/182 reads (13%) | catalogued as COSV66830423; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | catalogued as rs760757380; called by mutect2, varscan2
- HSD11B2 | c.738C>G p.F246L | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.048); catalogued as COSV99341096; called by muse, mutect2
- IGSF10 | c.2803A>G p.M935V | Missense Mutation (SNP) | VAF 86/451 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV56783028; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1690C>G p.L564V | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100781111; called by muse, mutect2
- ITGA6 | c.3073G>A p.E1025K (on ENST00000442250; = p.E986K on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.135); catalogued as rs1485792506, COSV51221108; called by muse, mutect2, varscan2
- KCNB2 | c.1417G>T p.G473* | Nonsense Mutation (SNP) | VAF 13/96 reads (14%) | catalogued as COSV101578732, COSV73050052; called by muse, mutect2, varscan2
- KIF17 | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs1414901196, COSV56116967; called by muse, mutect2, varscan2
- KLRF1 | c.67T>C p.S23P | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV54380568; called by muse, mutect2, varscan2
- LRIG1 | c.2137C>A p.Q713K | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV56238468; called by muse, mutect2, varscan2
- LRP2 | c.7716G>C p.L2572= | Splice Region (SNP) | VAF 7/66 reads (11%) | catalogued as COSV99787631; called by muse, mutect2
- LZTS2 | c.1658C>T p.A553V | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.324); catalogued as rs550892828, COSV64651260; called by muse, mutect2, varscan2
- MOGAT2 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.053); catalogued as rs781112029, COSV52218790, COSV52221577; called by muse, mutect2, varscan2
- MPHOSPH6 | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.566); catalogued as COSV99259159; called by muse, mutect2
- MTOR | c.3107C>A p.T1036N | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.084); catalogued as COSV63869503; called by muse, mutect2, varscan2
- NOTCH3 | c.171G>T p.Q57H | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.652); catalogued as COSV54630188; called by muse, mutect2
- PCDHB13 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 45/437 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs781868085, COSV99507096; called by muse, mutect2, varscan2
- PCNX1 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.01); catalogued as COSV53091515; called by muse, mutect2, varscan2
- PIK3CA | c.38T>C p.I13T | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as COSV55900386; called by muse, mutect2, varscan2
- PITPNM3 | c.2876C>T p.P959L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV51470478; called by muse, mutect2, varscan2
- POLR1A | c.1693C>T p.R565C | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV55694031, COSV99807907; called by muse, mutect2
- PRPS1L1 | c.731T>C p.V244A | Missense Mutation (SNP) | VAF 20/337 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as COSV72649852; called by muse, mutect2
- PRR14 | c.308A>C p.Q103P | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.466); catalogued as COSV54911147; called by muse, mutect2, varscan2
- PTOV1 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs764053837, COSV55587063; called by muse, mutect2, varscan2
- PUS3 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV57102513; called by muse, mutect2, varscan2
- R3HDM4 | c.648C>G p.S216R | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV64292878; called by muse, mutect2, varscan2
- RBM38 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs766487046, COSV61133830; called by muse, mutect2, varscan2
- RNF150 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs373846181; called by muse, mutect2, varscan2
- RTN1 | c.1175C>T p.P392L | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs772853362, COSV50720293, COSV50737223; called by muse, mutect2, varscan2
- RXRG | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749399300, COSV63231692, COSV63231996; called by muse, mutect2, varscan2
- SACS | c.8971C>T p.R2991C | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.976); catalogued as rs759112797, COSV66537543; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLCO2A1 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60484491; called by muse, mutect2, varscan2
- STON1 | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1192173970, COSV100561720; called by muse, mutect2
- SUSD5 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as rs776179774, COSV58875454; called by muse, mutect2, varscan2
- SYNE1 | c.11414G>A p.R3805Q (on ENST00000367255 / NM_182961.4; = p.R3790Q on NM_033071.3) | Missense Mutation (SNP) | VAF 113/491 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754270893, COSV54921171, COSV55010734; called by muse, mutect2, varscan2
- SYNE1 | c.5414G>A p.R1805Q (on ENST00000367255 / NM_182961.4; = p.R1812Q on NM_033071.3) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs749200824, COSV55074337; called by muse, mutect2, varscan2
- TARBP2 | c.430C>G p.P144A (on ENST00000266987 / NM_134323.2; = p.P123A on NM_004178.4) | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs139126157, COSV57199269; called by muse, mutect2, varscan2
- TES | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64042077; called by muse, mutect2, varscan2
- TNN | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs767983713, COSV53423584; called by muse, mutect2, varscan2
- TNS1 | c.4612C>T p.L1538F | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50694842; called by muse, mutect2, varscan2
- TOX3 | c.517C>A p.Q173K | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV54864312, COSV54868435; called by muse, mutect2, varscan2
- TRIM15 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.34); catalogued as COSV64989192; called by muse, mutect2, varscan2
- TRPC5 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 68/112 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747130444, COSV53286728; called by muse, mutect2, varscan2
- UHRF1BP1L | c.535A>T p.T179S | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99691398; called by muse, mutect2
- ZC2HC1A | c.423T>A p.C141* | Nonsense Mutation (SNP) | VAF 17/315 reads (5%) | catalogued as COSV99803930; called by muse, mutect2
- ZNF358 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV51174470; called by muse, mutect2, varscan2
- ZNF594 | c.925C>A p.H309N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV68384942; called by muse, mutect2, varscan2
- ZNF597 | c.246T>G p.I82M | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as COSV100071967; called by muse, mutect2
- ZNF83 | c.1498C>T p.L500F | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs925824032, COSV56529047; called by muse, mutect2
- ITPKA | c.863_866dup p.K290Vfs*10 | Frame Shift Ins (INS) | VAF 56/207 reads (27%) | called by mutect2, pindel, varscan2
- LRP1B | c.9082dup p.I3028Nfs*2 | Frame Shift Ins (INS) | VAF 42/126 reads (33%) | called by mutect2, pindel, varscan2
- PIP4K2C | c.772_774del p.E258del | In Frame Del (DEL) | VAF 26/70 reads (37%) | called by pindel, varscan2
- ADAMTSL2 | c.501C>T p.D167= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as rs1418103492, COSV63203575; called by muse, mutect2, varscan2
- ATP6V0A1 | c.1479G>A p.T493= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as rs774138296, COSV52871621; called by muse, mutect2, varscan2
- BRSK1 | c.1413G>A p.P471= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100473890; called by muse, mutect2
- CACNB1 | c.339G>C p.P113= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as rs745782403, COSV59998393, COSV59999018; called by muse, mutect2, varscan2
- CD163 | c.2088G>A p.S696= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs536972277, COSV63129352, COSV63130268; called by muse, mutect2, varscan2
- CEP170B | c.2277C>T p.G759= (on ENST00000453495; = p.G688= on NM_015005.3) | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs905054487, COSV69023807; called by muse, mutect2, varscan2
- CEP97 | c.1125G>A p.T375= | Silent (SNP) | VAF 17/127 reads (13%) | catalogued as rs776938685, COSV59123493; called by muse, mutect2, varscan2
- CPEB3 | c.1044G>A p.S348= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as rs370861375, COSV56454820; called by muse, mutect2, varscan2
- CYP2B6 | c.927C>T p.Y309= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as rs768992518, COSV57842984; called by muse, mutect2
- DCAF12L1 | c.639C>T p.R213= | Silent (SNP) | VAF 30/111 reads (27%) | catalogued as rs375986905, COSV64421386; called by muse, mutect2, varscan2
- DIDO1 | c.6627C>T p.R2209= | Silent (SNP) | VAF 40/485 reads (8%) | catalogued as COSV99825422; called by muse, mutect2
- DNAH11 | c.2736C>T p.D912= | Silent (SNP) | VAF 16/202 reads (8%) | catalogued as rs780377373, COSV60947309; called by muse, mutect2
- DNAH11 | c.5940G>T p.G1980= | Silent (SNP) | VAF 28/291 reads (10%) | catalogued as COSV100178569, COSV60960297; called by muse, mutect2
- DNAH17 | c.4518C>T p.S1506= | Silent (SNP) | VAF 32/148 reads (22%) | catalogued as rs536643419, COSV67751427; called by muse, mutect2, varscan2
- EWSR1 | c.852A>G p.G284= | Silent (SNP) | VAF 47/104 reads (45%) | catalogued as COSV58422494; called by muse, mutect2, varscan2
- FANCE | c.411G>A p.G137= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV57689448; called by muse, mutect2, varscan2
- FBN1 | c.7230C>T p.H2410= | Silent (SNP) | VAF 19/103 reads (18%) | catalogued as rs193922231, COSV57327417; ClinVar: likely benign; called by muse, mutect2, varscan2
- HAO1 | c.357G>A p.A119= | Silent (SNP) | VAF 32/259 reads (12%) | catalogued as rs373499154, COSV66491055; called by muse, mutect2, varscan2
- HGF | c.1557C>T p.C519= | Silent (SNP) | VAF 9/100 reads (9%) | catalogued as rs1258858592, COSV55944770; called by muse, mutect2
- IRX1 | c.540C>T p.N180= | Silent (SNP) | VAF 18/267 reads (7%) | catalogued as COSV57360170; called by muse, mutect2
- JPH3 | c.1923C>T p.D641= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as rs749538454, COSV52465723; called by muse, mutect2, varscan2
- LPA | c.2715C>T p.D905= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as rs748928708, COSV60299134; called by muse, mutect2
- LRFN1 | c.330C>T p.A110= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as rs756152292, COSV50436544; called by muse, mutect2, varscan2
- MYOM2 | c.183G>A p.T61= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs771222686, COSV50702789; called by muse, mutect2, varscan2
- NBPF1 | c.1212G>A p.P404= | Silent (SNP) | VAF 20/204 reads (10%) | catalogued as rs375545829; called by muse, mutect2, varscan2
- PCDH17 | c.930C>T p.D310= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV64972896; called by muse, mutect2
- PTPN13 | c.495A>G p.S165= | Silent (SNP) | VAF 12/185 reads (6%) | catalogued as rs1192878716, COSV100364533; called by muse, mutect2
- RTN4RL1 | c.147G>A p.P49= | Silent (SNP) | VAF 32/83 reads (39%) | catalogued as rs371594240; called by muse, mutect2, varscan2
- SETBP1 | c.4602G>A p.P1534= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99952747; called by muse, varscan2
- SOGA1 | c.951C>G p.L317= | Silent (SNP) | VAF 14/196 reads (7%) | catalogued as COSV99413417; called by muse, mutect2
- SRGAP3 | c.102T>C p.C34= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV64531645; called by muse, mutect2, varscan2
- UBAP2 | c.1200T>C p.S400= | Silent (SNP) | VAF 83/595 reads (14%) | catalogued as COSV62545752; called by muse, mutect2, varscan2
- UGT1A10 | c.441G>C p.L147= | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as rs766629881, COSV100761644; called by muse, mutect2, varscan2
- UIMC1 | c.1125T>C p.D375= | Silent (SNP) | VAF 33/148 reads (22%) | catalogued as COSV65893292; called by muse, mutect2, varscan2
- WDFY1 | c.18C>T p.H6= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as rs781745929, COSV51788583; called by muse, mutect2
